Gene-level copy-number profile of tumor specimen TCGA-DX-AB36-01A from TCGA case TCGA-DX-AB36, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-DX-AB36-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.d764ec7c-bfd0-4cd4-8058-5b083f30dd76.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB36-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4b84c34c-6c76-4c17-bd03-6dd1f1eb681f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,148; copy number 3: 5,988; copy number 4: 48,007; copy number 5: 440; copy number 6: 242; copy number 7: 1,433; copy number 8: 31; copy number 9: 10; copy number 10: 26; copy number 11: 4; copy number 12: 117; copy number 13: 4; copy number 14: 8; copy number 16: 12; copy number 17: 3; copy number 18: 3; copy number 19: 19; copy number 20: 6; copy number 23: 8; copy number 24: 7; copy number 25: 2; copy number 26: 1; copy number 27: 8; copy number 28: 20; copy number 30: 31; copy number 31: 5; copy number 34: 2; copy number 35: 23; copy number 36: 5; copy number 37: 16; copy number 38: 1; copy number 40: 9; copy number 42: 9; copy number 43: 1; copy number 44: 9; copy number 45: 11; copy number 46: 6; copy number 48: 32; copy number 49: 21; copy number 50: 5; copy number 51: 20; copy number 52: 15; copy number 57: 21; copy number 58: 11; copy number 64: 4; copy number 67: 1; copy number 73: 1; copy number 78: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB36-01A-11D-A416-01): tumor purity 0.99, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 519 genes in 70 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,050,918–52,366,205, 12 genes, copy number 49 (within-gene range 4–49): TXNDC12-AS1, BTF3L4, ZFYVE9, RN7SL788P, AL139156.2, AL139156.1, PDCL3P6, AL139156.3, DNAJC19P7, ANAPC10P1, CC2D1B, AL513218.1.
- chr1:55,376,526–55,484,972, 3 genes, copy number 42: RN7SKP291, RNU6-830P, Y_RNA.
- chr1:56,619,409–56,826,920, 4 genes, copy number 16: AC099789.1, PRKAA2, FYB2, AL360295.1.
- chr1:56,929,207–58,546,734, 6 genes, copy number 45 (within-gene range 4–57): C8B, AL161740.1, DAB1, AL390243.1, RPS20P5, DAB1-AS1.
- chr1:58,228,682–59,810,647, 21 genes, copy number 57 (within-gene range 4–57): AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY.
- chr1:70,411,218–70,439,851, 2 genes, copy number 10: CTH, Metazoa_SRP.
- chr1:72,274,552–72,899,240, 7 genes, copy number 52–78: GDI2P2, AL513166.1, RPL31P12, AL583808.1, RNU6-1246P, LINC02796, LINC02797.
- chr5:135,742,462–139,333,365, 80 genes, copy number 12 (broad region; genes not listed).
- chr9:14,850,429–15,362,134, 8 genes, copy number 13–20: RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33.
- chr9:88,627,063–88,803,716, 3 genes, copy number 48: LINC02843, AL390791.1, MIR4289.
- chr11:18,153,277–18,634,791, 30 genes, copy number 30: MRGPRX12P, MRGPRX4, GLTPP1, MRGPRX13P, SLC25A51P4, SAA4, SAA2-SAA4, SAA2, RNA5SP333, ST13P5, SAA1, RNA5SP334, HPS5, GTF2H1, MIR3159, LDHA, AC084117.1, LDHC, AC027544.3, LDHAL6A, TSG101, YWHABP2, AC027544.2, AC027544.1, UEVLD, Metazoa_SRP, SPTY2D1OS, AC112694.1, AC112694.2, SPTY2D1.
- chr11:18,956,055–19,308,358, 10 genes, copy number 19: MRGPRX11P, MRGPRX10P, MRGPRX9P, MRGPRX2, ZDHHC13, CSRP3, CSRP3-AS1, E2F8, PCNAP4, AC009652.1.
- chr11:19,380,484–19,591,291, 6 genes, copy number 19–36: NAV2-IT1, RNA5SP335, NAV2-AS5, NAV2-AS4, MIR4486, AC023950.1.
- chr11:20,363,685–20,509,338, 2 genes, copy number 31: HTATIP2, PRMT3.
- chr11:29,713,909–30,017,030, 3 genes, copy number 23 (within-gene range 3–23): AC107973.1, LINC01616, KCNA4.
- chr11:34,853,094–36,593,156, 34 genes, copy number 28–37 (within-gene range 3–37): APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1.
- chr11:37,702,125–38,212,799, 5 genes, copy number 24: AC061997.1, RPL7AP56, LINC02760, AC103798.1, LRRC6P1.
- chr11:38,618,264–38,686,323, 2 genes, copy number 34: LINC02759, LINC01493.
- chr11:77,473,371–77,821,017, 10 genes, copy number 40–43: AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1.
- chr12:49,265,156–49,568,145, 12 genes, copy number 12: AC125611.3, AC125611.4, PRPH, TROAP, C1QL4, DNAJC22, SPATS2, AC125611.2, AC125611.1, AC020612.4, KCNH3, MCRS1.
- chr12:50,504,985–50,757,433, 5 genes, copy number 10 (within-gene range 4–10): DIP2B, RNU6-769P, RNU6-238P, Y_RNA, AC013244.1.
- chr12:53,935,328–54,189,008, 33 genes, copy number 10–35: HOXC13-AS, HOXC13, HOXC12, HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6, HOXC11, HOXC-AS3, HOXC10, AC012531.3, HOXC6, MIR196A2, HOXC-AS2, HOXC9, HOXC-AS1, HOXC8, HOXC4, AC012531.2, AC012531.1, HOXC5, MIR615, FLJ12825, AC023794.3, AC023794.2, FAM242C, Y_RNA, SMUG1, LINC02381, AC023794.5, AC023794.4, AC023794.1.
- chr12:57,623,409–57,984,761, 29 genes, copy number 48 (within-gene range 4–48): B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:65,466,820–65,663,299, 5 genes, copy number 50 (within-gene range 50–61): AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3.
- chr12:65,934,777–66,343,643, 16 genes, copy number 11–45: AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB.
- chr12:67,329,014–67,352,039, 2 genes, copy number 12 (within-gene range 4–12): AC078983.1, MRPL40P1.
- chr12:67,929,235–67,978,387, 2 genes, copy number 19: LINC01479, AC005294.1.
- chr12:68,805,011–68,850,686, 5 genes, copy number 42: AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr12:69,239,569–69,579,793, 11 genes, copy number 58: CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2.
- chr12:70,515,870–70,920,738, 4 genes, copy number 14 (within-gene range 4–14): PTPRB, AC083809.1, PTPRR, FAHD2P1.
- chr12:78,352,519–78,794,114, 4 genes, copy number 31–73 (within-gene range 6–73): AC128707.1, AC130415.1, AC079362.1, AC068993.1.
- chr12:82,481,118–82,515,817, 3 genes, copy number 64: AC089998.4, AC089998.2, AC089998.1.
- chr12:82,686,880–84,672,026, 10 genes, copy number 14–24 (within-gene range 4–85): TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1, AC090679.3, AC090679.2, AC090679.1, AC087888.1, AC093027.1.
- chr12:89,010,681–90,100,763, 22 genes, copy number 11–51 (within-gene range 6–51): LINC02458, AC006199.1, RNU7-120P, MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1, POC1B, CENPCP1, POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2, AC025034.1, ATP2B1, ATP2B1-AS1, AC009522.1, RNA5SP365, MRPL2P1, RNU6-148P.
- chr12:89,947,693–90,300,974, 3 genes, copy number 19: LINC02399, AC126178.1, LINC02392.
- chr12:95,076,749–95,309,984, 9 genes, copy number 49 (within-gene range 4–49): FGD6, AC126615.2, AC126615.1, VEZT, Y_RNA, CBX3P5, RNU6-808P, MIR331, MIR3685.
- chr12:96,160,692–96,400,480, 7 genes, copy number 27: LINC02452, ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P, AC125612.1.
- chr12:108,858,932–110,073,686, 38 genes, copy number 9–52: DAO, SVOP, RNU6-361P, AC190387.1, USP30, USP30-AS1, RNA5SP372, ALKBH2, UNG, AC007637.1, ACACB, FOXN4, MYO1H, LINC01486, AC007570.1, KCTD10, UBE3B, MMAB, RNU4-32P, MVK, RN7SKP250, FAM222A, FAM222A-AS1, TRPV4, MIR4497, GLTP, AC007834.2, RN7SL441P, AC007834.1, TCHP, GIT2, AC084876.1, AC084876.2, ANKRD13A, C12orf76, AC007546.1, AC007546.3, AC007546.2.
- chr12:116,548,105–116,738,070, 6 genes, copy number 10: MAP1LC3B2, AC125603.4, AC125603.3, AC125603.2, AC125603.1, SPRING1.
- chr18:46,080,248–46,657,220, 8 genes, copy number 23–46 (within-gene range 2–46): ATP5F1A, HAUS1, RNU6-1278P, C18orf25, RNF165, AC015959.1, AC018931.1, LOXHD1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
